Somatic mutation profile of tumor specimen RC-B666-TBP1-A (aliquot RC-B666-TBP1-A-1-0-D-A93N-47) from RC case RC-B666, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: T-cell large granular lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.0 years (21,191 days).
Specimen RC-B666-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 227090b4-37c3-4d56-8b9c-e888ee434688.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B666-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B666-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4528bab4-7677-4db6-90a5-0b334f22ed8a

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEIOC | c.2443C>T p.R815* | Nonsense Mutation (SNP) | VAF 16/194 reads (8%) | catalogued as COSV63440487; called by muse, mutect2
- TAF11 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1289494046; called by muse, mutect2
- TSHZ1 | c.2498G>A p.R833Q (on ENST00000580243 / NM_001308210.2; = p.R788Q on NM_005786.6) | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.92); catalogued as rs781707604, COSV59010697; called by muse, mutect2
- EXOC2 | c.111C>A p.D37E | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OSBPL8 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 14/151 reads (9%) | called by muse, mutect2
- P4HA3 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.029); called by muse, mutect2
- PACS2 | c.1709A>G p.Q570R | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2
- CSMD1 | c.5979T>G p.G1993= (on ENST00000520002; = p.G1992= on NM_033225.6) | Silent (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- CYP27B1 | c.615G>T p.S205= | Silent (SNP) | VAF 16/215 reads (7%) | catalogued as rs572765133; called by muse, mutect2
- GIMD1 | c.18G>A p.K6= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- GPR85 | c.756A>C p.T252= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
